Gene-level copy-number profile of tumor specimen TCGA-22-5481-01A from TCGA case TCGA-22-5481, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 72.3 years (26,419 days).
Specimen TCGA-22-5481-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.a4a2c073-a1ae-4ab0-aba7-a1a30a9eb6c0.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-22-5481-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 816 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/3f9bb322-59b8-479e-8235-231a605c8a04

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,714; copy number 2: 16,985; copy number 3: 23,461; copy number 4: 13,616; copy number 5: 1,337; copy number 6: 625; copy number 7: 482; copy number 8: 117; copy number 9: 160; copy number 10: 57; copy number 11: 125; copy number 12: 12; copy number 14: 116.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-22-5481-01A-31D-1943-01): tumor purity 0.7, ploidy 3, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,069 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:4,511,959–5,513,809, 34 genes, copy number 8: CYP3A54P, AC072054.1, FOXK1, AC092428.1, AP5Z1, MIR4656, AC092610.1, RADIL, Y_RNA, PAPOLB, RPL22P16, MMD2, RNF216P1, AC092032.2, RBAK-RBAKDN, AC092032.3, AC092032.1, SPDYE19P, RBAK, RBAKDN, OR10AH1P, ZNF890P, RNU6-215P, WIPI2, SLC29A4, TNRC18, AC093620.1, AC092171.1, AC092171.4, AC092171.3, AC092171.5, FBXL18, AC092171.2, MIR589.
- chr8:103,500,696–104,256,094, 1 gene, copy number 7 (within-gene range 4–7): RIMS2.
- chr8:103,768,281–139,508,971, 392 genes, copy number 7 (broad region; genes not listed).
- chr14:18,333,726–20,060,983, 89 genes, copy number 7 (broad region; genes not listed).
- chr17:21,655,843–22,532,522, 29 genes, copy number 9: AC233702.4, AC233702.9, KCNJ18, AC243725.1, ABBA01006766.1, NCOR1P2, UBBP4, FTLP13, LINC02002, AC138761.1, AC138761.2, FAM27E5, AC087575.1, FLJ36000, AC132825.3, AC132825.4, MTND6P35, MTCYBP13, MTRNR2L1, AC132825.2, MTND1P15, MTND2P13, AC132825.1, NMTRS-TGA3-1, MTATP6P3, MTCO3P13, AC132825.6, AC132825.7, AC132825.5.
- chr17:43,211,835–45,490,749, 131 genes, copy number 9 (broad region; genes not listed).
- chr19:31,348,881–40,122,168, 393 genes, copy number 8–14 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,511. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
